Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8SJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8SJ-01B (Primary Tumor).

PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: ___%

4: 100%

5: ___%

TUMOR LOCATION

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

NOT REPORTED

SEMINAL VESICAL INVASION

PRESENT

LEFT

SURGICAL MARGINS

FREE OF INVASIVE CARCINOMA

LYMPHOVASCULAR INVASION

ABSENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 20%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT NODAL STATION

NUMBER OF NODES IDENTIFIED: 19

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT NODAL STATION

NUMBER OF NODES IDENTIFIED: 10

NUMBER OF NODES INVOLVED BY METASTASIS: 0

ADDITIONAL PATHOLOGIC FINDINGS

NONE

PATHOLOGICAL STAGING

pT3b

pN0

pMx

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
J 4/22/14

Source: NCI Genomic Data Commons file 3ed82e26-1f40-4aab-8a62-995574c855e4 (TCGA-YL-A8SJ.86F65B00-7E83-4013-85E8-A4AE42686ACF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).